Somatic mutation profile of tumor specimen 0DTLGN from CCDI case PBCJTK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 5.2 years (1,917 days).
Specimen 0DTLGN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78c8899d-c14a-46d9-9f19-798a6eb53c84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTLGG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ef866ff-af8f-4cb0-8893-33b0c0247e09

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZEB2 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 98/532 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs746958005, COSV57955437; called by muse, mutect2, varscan2
- RELN | c.3370A>G p.T1124A | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- AGBL3 | c.1788C>A p.V596= | Silent (SNP) | VAF 69/367 reads (19%) | catalogued as COSV51950004; called by mutect2, varscan2
- CCDC177 | c.267C>T p.Y89= | Silent (SNP) | VAF 94/327 reads (29%) | called by muse, mutect2, varscan2
